Somatic mutation profile of tumor specimen C3L-07954-02 (aliquot CPT0451930006) from CPTAC case C3L-07954, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 75.3 years (27,509 days).
Specimen C3L-07954-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pylorus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf359f36-2a78-4d3d-b2a2-94c972cc0a71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07954-31 (Blood Derived Normal), aliquot CPT0452070004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48d9d781-a61b-4711-90b2-490eda0f1b8b

The open-access MAF lists 110 somatic variants for this specimen: 78 protein-altering or splice-affecting, 29 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 29, Intron 3, Nonsense Mutation 2, Splice Region 2, Splice Site 2, Frame Shift Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN5A | c.3908G>A p.R1303Q (on ENST00000333535 / NM_198056.3; = p.R1302Q on NM_000335.5) | Missense Mutation (SNP) | VAF 19/474 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs977717858, COSV61119181; ClinVar: likely pathogenic; called by muse, mutect2
- ADAM28 | c.260A>C p.Y87S | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as COSV56101752; called by muse, mutect2
- APLP1 | c.1933C>T p.R645C (on ENST00000221891 / NM_001024807.3; = p.R644C on NM_005166.4) | Missense Mutation (SNP) | VAF 18/470 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55705611; called by muse, mutect2
- BRICD5 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 32/589 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.041); catalogued as rs188245691, COSV57029259; called by muse, mutect2
- C4orf54 | c.638T>A p.L213H | Missense Mutation (SNP) | VAF 19/392 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.428); catalogued as COSV101552088, COSV72766807, COSV72767127; called by muse, mutect2
- C6orf136 | c.72+8G>A | Splice Region (SNP) | VAF 34/764 reads (4%) | catalogued as rs1441605882; called by muse, mutect2
- CCDC54 | c.346G>T p.E116* | Nonsense Mutation (SNP) | VAF 13/397 reads (3%) | catalogued as COSV53758743; called by muse, mutect2
- CDH4 | c.2461G>T p.E821* | Nonsense Mutation (SNP) | VAF 28/762 reads (4%) | catalogued as COSV100848478; called by muse, mutect2
- CLEC12A | c.442A>G p.S148G | Missense Mutation (SNP) | VAF 25/442 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.104); catalogued as COSV100429765, COSV58561507; called by muse, mutect2
- COL4A6 | c.4645G>A p.A1549T | Missense Mutation (SNP) | VAF 39/788 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766360534, COSV57866479; called by muse, mutect2
- CTNNA2 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 18/366 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756543455, COSV100782637, COSV63546169; called by muse, mutect2
- FHL3 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 27/508 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs201589522; called by muse, mutect2
- GALNT9 | c.237C>T p.N79= | Splice Region (SNP) | VAF 31/350 reads (9%) | catalogued as rs1555246710, COSV61101984, COSV61103546; called by muse, mutect2
- GPR26 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 34/638 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1389105852, COSV52934644; called by muse, mutect2
- GRIN2A | c.1255G>A p.V419M | Missense Mutation (SNP) | VAF 26/440 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58020274; called by muse, mutect2
- HOMER2 | c.611C>T p.S204L (on ENST00000304231 / NM_199330.3; = p.S193L on NM_004839.4) | Missense Mutation (SNP) | VAF 24/492 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as rs369621004; called by muse, mutect2
- KCNB2 | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 36/501 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.435); catalogued as rs985476287; called by muse, mutect2
- KRT79 | c.1270C>T p.R424W | Missense Mutation (SNP) | VAF 24/428 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs200262123; called by muse, mutect2
- LRIT1 | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 32/571 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.226); catalogued as rs1359984056; called by muse, mutect2
- LRRN2 | c.539T>C p.I180T | Missense Mutation (SNP) | VAF 30/512 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as rs111660514, COSV65784344; called by muse, mutect2
- MAGEC3 | c.832C>T p.L278F | Missense Mutation (SNP) | VAF 28/630 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV71610055; called by muse, mutect2
- NFASC | c.253G>A p.A85T (on ENST00000339876 / NM_001378329.1; = p.A79T on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/402 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as rs769904507, COSV58365528; called by muse, mutect2
- OR13H1 | c.554A>C p.K185T | Missense Mutation (SNP) | VAF 36/640 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58548133; called by muse, mutect2
- PABPC3 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 62/489 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs770872268, COSV55798427; called by muse, mutect2, varscan2
- PGAP4 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 26/468 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs549863880, COSV66388409; called by muse, mutect2
- SETD1A | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 26/500 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs761673509; called by muse, mutect2
- SHANK1 | c.3500G>A p.S1167N | Missense Mutation (SNP) | VAF 36/698 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV53251761; called by muse, mutect2
- SOHLH2 | c.158C>T p.T53M | Missense Mutation (SNP) | VAF 58/378 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs142901524; called by muse, varscan2
- TMC3 | c.2943G>T p.Q981H | Missense Mutation (SNP) | VAF 31/475 reads (7%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV100846036; called by muse, mutect2
- TRAJ26 | c.37G>A p.G13R | Missense Mutation (SNP) | VAF 20/350 reads (6%) | catalogued as rs763625454; called by muse, mutect2
- TRPV4 | c.2560G>A p.D854N | Missense Mutation (SNP) | VAF 40/518 reads (8%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as rs368963822, COSV55684264; ClinVar: uncertain significance; called by muse, mutect2
- VSTM1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 26/647 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753821114, COSV58076284; called by muse, mutect2
- ZBED1 | c.974C>G p.S325C | Missense Mutation (SNP) | VAF 25/869 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV58129632; called by muse, mutect2
- ZDHHC5 | c.1819C>T p.R607C | Missense Mutation (SNP) | VAF 30/622 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.725); catalogued as rs772985153; called by muse, mutect2
- ZNF536 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 50/674 reads (7%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.361); catalogued as COSV100835935; called by muse, mutect2
- ZNF831 | c.1775C>T p.A592V | Missense Mutation (SNP) | VAF 56/762 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as rs200891052; called by muse, mutect2
- ZNF865 | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 28/634 reads (4%) | SIFT tolerated (0.58); catalogued as rs1321801646; called by muse, mutect2
- ABRA | c.211T>A p.S71T | Missense Mutation (SNP) | VAF 64/524 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0); called by mutect2, varscan2
- ANOS1 | c.1634C>G p.S545C | Missense Mutation (SNP) | VAF 15/341 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.619); called by muse, mutect2
- ATP8B2 | c.1190T>C p.F397S (on ENST00000672630; = p.F364S on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/379 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2
- BCORL1 | c.4666T>A p.S1556T | Missense Mutation (SNP) | VAF 21/536 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.151); called by muse, mutect2
- C8orf34 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 17/440 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.024); called by muse, mutect2
- CACNA1B | c.2405C>T p.T802M | Missense Mutation (SNP) | VAF 28/582 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.107); called by muse, mutect2
- CCT8L2 | c.1231G>A p.G411R | Missense Mutation (SNP) | VAF 25/492 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CLCN6 | c.437T>G p.L146R | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2
- CNOT1 | c.1237C>T p.L413F | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2
- DOCK6 | c.5234A>G p.E1745G | Missense Mutation (SNP) | VAF 12/385 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2
- ENPP2 | c.972+1G>A p.X324_splice | Splice Site (SNP) | VAF 11/261 reads (4%) | called by muse, mutect2
- FHL1 | c.970T>A p.*324Rext*32 (on ENST00000651089 / NM_001369326.1; = p.V257E on NM_001449.5 and 2 other RefSeq transcripts) | Nonstop Mutation (SNP) | VAF 26/648 reads (4%) | called by muse, mutect2
- GNA15 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 13/454 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.429); called by muse, mutect2
- HEATR1 | c.338G>T p.C113F | Missense Mutation (SNP) | VAF 19/322 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- IL1RAPL2 | c.794G>A p.C265Y | Missense Mutation (SNP) | VAF 16/342 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2
- MAGEC1 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 24/645 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); called by muse, mutect2
- MYO16 | c.1994T>A p.I665N | Missense Mutation (SNP) | VAF 12/342 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- NPAP1 | c.1521C>G p.F507L | Missense Mutation (SNP) | VAF 20/598 reads (3%) | SIFT tolerated (0.41); PolyPhen benign (0.015); called by muse, mutect2
- NPC1L1 | c.758C>T p.T253I | Missense Mutation (SNP) | VAF 25/600 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2
- NPY1R | c.997T>G p.F333V | Missense Mutation (SNP) | VAF 18/460 reads (4%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2
- NUP98 | c.1199G>T p.G400V | Missense Mutation (SNP) | VAF 16/354 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR2T11 | c.524dup p.C176Lfs*2 | Frame Shift Ins (INS) | VAF 19/199 reads (10%) | called by mutect2, pindel
- OR2Y1 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 19/459 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- PCDH9 | c.677A>T p.D226V | Missense Mutation (SNP) | VAF 48/540 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCLO | c.5936A>T p.E1979V | Missense Mutation (SNP) | VAF 26/514 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); called by muse, mutect2
- PKNOX2 | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 14/333 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PSG9 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 16/393 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RFTN1 | c.904C>A p.L302I | Missense Mutation (SNP) | VAF 17/506 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); called by muse, mutect2
- SEC16B | c.13G>C p.A5P | Missense Mutation (SNP) | VAF 13/320 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); called by muse, mutect2
- SEMA4B | c.2360A>G p.Y787C | Missense Mutation (SNP) | VAF 39/674 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SH3RF1 | c.996C>G p.I332M | Missense Mutation (SNP) | VAF 46/646 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SLC44A4 | c.342+1G>A p.X114_splice | Splice Site (SNP) | VAF 42/494 reads (9%) | called by muse, mutect2
- SPATS2 | c.940A>G p.K314E | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- SYT4 | c.626G>A p.R209K | Missense Mutation (SNP) | VAF 30/425 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- TACC2 | c.5116G>A p.E1706K | Missense Mutation (SNP) | VAF 21/635 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2
- TRAV30 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 16/397 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- TTN | c.31693G>A p.E10565K (on ENST00000591111; = p.E9638K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/268 reads (4%) | PolyPhen benign (0.442); called by muse, mutect2
- ZFP3 | c.1265A>C p.Q422P | Missense Mutation (SNP) | VAF 34/482 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZHX3 | c.2170C>T p.P724S | Missense Mutation (SNP) | VAF 23/518 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF275 | c.799T>A p.C267S | Missense Mutation (SNP) | VAF 32/522 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- ZNF75D | c.479A>G p.K160R | Missense Mutation (SNP) | VAF 71/612 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ACACB | c.2016G>A p.L672= | Silent (SNP) | VAF 23/419 reads (5%) | called by muse, mutect2
- ARFGAP1 | c.600C>T p.L200= | Silent (SNP) | VAF 34/429 reads (8%) | called by muse, mutect2
- ASTN2 | c.1837C>T p.L613= (on ENST00000313400 / NM_001365069.1; = p.L562= on NM_014010.5) | Silent (SNP) | VAF 18/484 reads (4%) | called by muse, mutect2
- ATP7B | c.369C>A p.A123= | Silent (SNP) | VAF 13/440 reads (3%) | catalogued as COSV99666607; called by muse, mutect2
- BMP3 | c.1284C>A p.V428= | Silent (SNP) | VAF 16/285 reads (6%) | catalogued as COSV51081914; called by muse, mutect2
- FAAP100 | c.459G>A p.Q153= | Silent (SNP) | VAF 23/636 reads (4%) | called by muse, mutect2
- GFRAL | c.777T>C p.I259= | Silent (SNP) | VAF 21/494 reads (4%) | called by muse, mutect2
- GPC4 | c.147C>T p.L49= | Silent (SNP) | VAF 12/374 reads (3%) | called by muse, mutect2
- GSDMC | c.735C>T p.S245= | Silent (SNP) | VAF 22/314 reads (7%) | catalogued as rs765277111, COSV52699751; called by muse, mutect2
- GZMB | c.408G>A p.V136= | Silent (SNP) | VAF 16/558 reads (3%) | catalogued as COSV99362224; called by muse, mutect2
- HTR2C | c.150C>T p.D50= | Silent (SNP) | VAF 52/582 reads (9%) | catalogued as rs202042319; called by muse, mutect2
- KCNN2 | c.75C>T p.H25= (on ENST00000264773; = p.H237= on NM_021614.4) | Silent (SNP) | VAF 28/586 reads (5%) | catalogued as rs1288757441; called by muse, mutect2
- KLHL35 | c.93G>A p.L31= | Silent (SNP) | VAF 35/552 reads (6%) | called by muse, mutect2
- MED12L | c.5589C>T p.G1863= | Silent (SNP) | VAF 24/450 reads (5%) | catalogued as rs112306093; called by muse, mutect2
- MPRIP | c.2733G>A p.S911= | Silent (SNP) | VAF 34/271 reads (13%) | catalogued as rs146815991; called by muse, mutect2, varscan2
- NIN | c.3375G>A p.Q1125= | Silent (SNP) | VAF 28/472 reads (6%) | catalogued as rs765244656; called by muse, mutect2
- NKX1-1 | c.972C>T p.C324= | Silent (SNP) | VAF 52/558 reads (9%) | called by muse, mutect2
- NPEPL1 | c.288G>A p.T96= | Silent (SNP) | VAF 28/598 reads (5%) | catalogued as COSV100622324; called by muse, mutect2
- NR0B1 | c.420G>A p.P140= | Silent (SNP) | VAF 43/722 reads (6%) | catalogued as rs747649174, COSV66763980; called by muse, mutect2
- OR2T34 | c.540G>A p.L180= | Silent (SNP) | VAF 31/740 reads (4%) | catalogued as COSV60901100; called by muse, mutect2
- RYR2 | c.13038G>A p.G4346= | Silent (SNP) | VAF 25/485 reads (5%) | catalogued as COSV100772931; called by muse, mutect2
- SLC25A11 | c.15G>A p.A5= | Silent (SNP) | VAF 27/420 reads (6%) | catalogued as rs1293960146; called by muse, mutect2
- SLC25A33 | c.735C>T p.G245= | Silent (SNP) | VAF 18/325 reads (6%) | called by muse, mutect2
- TAF7L | c.75A>G p.V25= | Silent (SNP) | VAF 36/612 reads (6%) | called by muse, mutect2
- TENM3 | c.3804C>T p.D1268= | Silent (SNP) | VAF 24/422 reads (6%) | catalogued as rs369770052; called by muse, mutect2
- UBR4 | c.9G>A p.T3= | Silent (SNP) | VAF 38/538 reads (7%) | called by muse, mutect2
- WWC3 | c.387G>A p.R129= | Silent (SNP) | VAF 15/376 reads (4%) | called by muse, mutect2
- ZNF316 | c.1800C>T p.F600= | Silent (SNP) | VAF 50/798 reads (6%) | catalogued as rs914328738; called by muse, mutect2
- ZNF638 | c.2493C>T p.I831= | Silent (SNP) | VAF 16/312 reads (5%) | called by muse, mutect2
- ARMCX4 | c.1038+3827C>T | Intron (SNP) | VAF 38/922 reads (4%) | catalogued as rs782613951; called by muse, mutect2
- DST | c.4297-4588G>A | Intron (SNP) | VAF 24/394 reads (6%) | catalogued as rs370912424; ClinVar: likely benign; called by muse, mutect2
- MASP1 | c.1303+5351G>A | Intron (SNP) | VAF 44/648 reads (7%) | catalogued as COSV56224136; called by muse, mutect2
